Somatic mutation profile of tumor specimen TARGET-30-PATCFL-01A (aliquot TARGET-30-PATCFL-01A-01D) from TARGET case TARGET-30-PATCFL, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 2.9 years (1,041 days).
Specimen TARGET-30-PATCFL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba7ff2ed-c6cb-4dc8-8cea-0ec58efd62db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATCFL-10A (Blood Derived Normal), aliquot TARGET-30-PATCFL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/faa8cc0f-3890-478b-a19c-c6f2d95f8bbd

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OR1A1 | c.887A>G p.K296R | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
